Somatic mutation profile of tumor specimen TCGA-85-8287-01A (aliquot TCGA-85-8287-01A-11D-2293-08) from TCGA case TCGA-85-8287, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.3 years (26,401 days).
Specimen TCGA-85-8287-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c1250c7-16a1-4c0a-b58f-0f974e36f5f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8287-10A (Blood Derived Normal), aliquot TCGA-85-8287-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b72f240-95d4-4c14-ad7f-f494e180685a

The open-access MAF lists 275 somatic variants for this specimen: 211 protein-altering or splice-affecting, 60 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 60, Nonsense Mutation 14, Splice Site 10, Frame Shift Del 4, Intron 3, In Frame Del 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2960G>T p.S987I | Missense Mutation (SNP) | VAF 109/465 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs796053124, CM165166, COSV99332099; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1261T>G p.F421V | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV100266830; called by muse, mutect2, varscan2
- ABL2 | c.3085G>A p.A1029T (on ENST00000502732 / NM_007314.4; = p.A1014T on NM_005158.5) | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs370175435, COSV100772812; called by muse, mutect2, varscan2
- ABT1 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223254; called by muse, mutect2, varscan2
- AC004593.2 | c.840C>G p.N280K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99765283, COSV99766156; called by muse, mutect2
- ACSM2B | c.1630-1G>C p.X544_splice | Splice Site (SNP) | VAF 32/214 reads (15%) | catalogued as COSV100312796, COSV61656557; called by muse, mutect2, varscan2
- ACTA1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.337); catalogued as COSV100796751; called by muse, mutect2, varscan2
- ACVRL1 | c.1049-2A>T p.X350_splice | Splice Site (SNP) | VAF 28/83 reads (34%) | catalogued as COSV101187940; called by muse, mutect2, varscan2
- ANKLE2 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100514197; called by muse, mutect2, varscan2
- ANKS1B | c.3503T>C p.V1168A (on ENST00000547776 / NM_152788.4; = p.V334A on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100228156; called by muse, mutect2
- APBA1 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs374176608; called by muse, mutect2
- ARHGAP35 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV101351198; called by muse, mutect2, varscan2
- ATP10A | c.2033C>A p.A678D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as COSV100791325, COSV100791399; called by muse, mutect2, varscan2
- ATXN2L | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV100294544; called by muse, mutect2
- BAG6 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs770195862, COSV52989677; called by muse, mutect2, varscan2
- C1QTNF9 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100129932; called by muse, mutect2, varscan2
- C1QTNF9B | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV101158589; called by mutect2, varscan2
- C6orf118 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV100024622; called by muse, mutect2, varscan2
- C8A | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100776526; called by muse, mutect2, varscan2
- CA5B | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100590746; called by muse, mutect2
- CACNA1A | c.1909G>T p.G637C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100802623, COSV64198810; called by muse, mutect2, varscan2
- CALM1 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100811157; called by muse, mutect2, varscan2
- CALM1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100811158; called by muse, mutect2, varscan2
- CATSPERD | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.682); catalogued as rs755100442, COSV67537174; called by muse, mutect2, varscan2
- CCDC185 | c.1699A>G p.K567E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs1163029046, COSV100838810; called by muse, mutect2, varscan2
- CCDC85A | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV101339480; called by muse, mutect2
- CCKAR | c.1254C>A p.Y418* | Nonsense Mutation (SNP) | VAF 35/231 reads (15%) | catalogued as COSV99810331; called by muse, mutect2, varscan2
- CCKBR | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100582976, COSV58103264; called by muse, mutect2, varscan2
- CDHR3 | c.1930T>A p.W644R | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV100488459; called by muse, mutect2, varscan2
- CENPQ | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.026); catalogued as COSV100225781; called by muse, mutect2, varscan2
- CIITA | c.2978C>A p.A993E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV100162095, COSV60863858; called by muse, mutect2, varscan2
- CLSTN2 | c.1223-1G>T p.X408_splice | Splice Site (SNP) | VAF 13/146 reads (9%) | catalogued as COSV101515801; called by muse, mutect2
- CMKLR1 | c.79G>A p.V27I (on ENST00000312143 / NM_001142344.2; = p.V25I on NM_004072.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1287310083, COSV100379477; called by muse, mutect2, varscan2
- CNTN1 | c.2372G>C p.G791A | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100751526; called by muse, mutect2, varscan2
- CNTN5 | c.1952G>T p.R651M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.995); catalogued as COSV99678018; called by muse, mutect2, varscan2
- COL13A1 | c.1586A>G p.N529S (on ENST00000398978 / NM_001130103.2; = p.N472S on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as rs1255701557, COSV100637517; called by muse, mutect2, varscan2
- COL1A2 | c.2305G>A p.G769S | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV99800088; called by muse, mutect2, varscan2
- COL1A2 | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs72658184, COSV99800090; called by muse, mutect2, varscan2
- COL26A1 | c.820G>A p.A274T (on ENST00000313669 / NM_001278563.3; = p.A272T on NM_133457.4) | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.104); catalogued as rs748332700, COSV100561816; called by muse, mutect2, varscan2
- COL4A5 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100088057, COSV60372068; called by muse, mutect2, varscan2
- CR1L | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV100888429; called by muse, mutect2, varscan2
- CRYM | c.698G>C p.W233S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs748606222, COSV99561703, COSV99561825; called by muse, mutect2, varscan2
- CSMD3 | c.1421-1G>A p.X474_splice (on ENST00000297405 / NM_001363185.1; = p.X370_splice on NM_052900.3) | Splice Site (SNP) | VAF 26/118 reads (22%) | catalogued as COSV52325105; called by muse, mutect2, varscan2
- CSN2 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs776355136, COSV100778785; called by muse, mutect2
- CST1 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV100494347; called by muse, mutect2, varscan2
- CYRIB | c.313A>T p.R105* | Nonsense Mutation (SNP) | VAF 37/96 reads (39%) | catalogued as COSV101310114; called by muse, mutect2, varscan2
- DDR1 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as COSV100241675; called by muse, mutect2
- DDX60L | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52715317, COSV99487748; called by muse, mutect2, varscan2
- DLG5 | c.4223A>T p.Q1408L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100967568; called by muse, mutect2, varscan2
- DNAJC6 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs766961674, COSV99674708; called by muse, mutect2, varscan2
- DPY19L1 | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100204756, COSV60580890; called by muse, mutect2, varscan2
- DPYSL5 | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56512294, COSV99982477; called by muse, mutect2, varscan2
- ECHDC2 | c.769G>T p.G257W (on ENST00000371522 / NM_001198961.2; = p.G226W on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100597650; called by muse, mutect2, varscan2
- ENPP3 | c.914G>T p.W305L | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717467; called by muse, mutect2, varscan2
- EPC1 | c.1880A>T p.Q627L | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as COSV99553030; called by muse, mutect2, varscan2
- EPHA3 | c.1959G>C p.K653N | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100345968, COSV60706052; called by muse, mutect2
- ERICH1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.625); catalogued as rs143811367; called by muse, mutect2, varscan2
- EZH1 | c.1130C>G p.A377G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV101331385; called by muse, mutect2, varscan2
- FAM13C | c.1732A>C p.K578Q | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99514010; called by muse, mutect2, varscan2
- FAM217A | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99212738; called by muse, mutect2, varscan2
- FAM53C | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV99524430; called by muse, mutect2, varscan2
- FANCD2 | c.1992C>A p.F664L | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99811576; called by mutect2, varscan2
- FASTKD3 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99241241, COSV99241814; called by muse, varscan2
- FASTKD3 | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99241815; called by muse, varscan2
- FGF23 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs780315628, COSV99426493; called by muse, mutect2, varscan2
- FHDC1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV52600101; called by muse, mutect2, varscan2
- FRMPD2 | c.2077G>T p.G693C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100563897; called by muse, mutect2, varscan2
- GATA3 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100651054, COSV60520722; called by muse, mutect2
- GEMIN5 | c.3178G>T p.A1060S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV99594007, COSV99594011; called by muse, mutect2, varscan2
- GFRAL | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV100475322; called by muse, mutect2, varscan2
- GPATCH8 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs752223254, COSV59197803; called by mutect2, varscan2
- GPR174 | c.339T>A p.S113R | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99338189; called by muse, mutect2, varscan2
- GRIN2A | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV100410155, COSV58027171; called by muse, mutect2, varscan2
- GRM8 | c.1710G>C p.Q570H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.308); catalogued as COSV100283636; called by muse, mutect2, varscan2
- GSDMA | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV99227867; called by muse, varscan2
- GUCA1C | c.83T>C p.M28T | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99226482; called by muse, mutect2, varscan2
- HDLBP | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | catalogued as COSV100190965; called by muse, mutect2, varscan2
- HIVEP1 | c.2773G>C p.G925R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101045205; called by muse, mutect2, varscan2
- HIVEP1 | c.2959G>T p.G987* | Nonsense Mutation (SNP) | VAF 50/313 reads (16%) | catalogued as COSV101045207; called by muse, varscan2
- HIVEP1 | c.3095G>T p.R1032M | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101045208; called by muse, varscan2
- HIVEP1 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV101045209; called by muse, varscan2
- HIVEP1 | c.4267G>C p.E1423Q | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101045210, COSV65103297; called by muse, mutect2, varscan2
- HIVEP2 | c.2169C>G p.I723M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV50006993, COSV99173830; called by muse, mutect2
- IGFN1 | c.1802T>A p.L601Q (on ENST00000295591 / NM_001367841.1; = p.L3058Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.179); catalogued as COSV99812649; called by muse, mutect2, varscan2
- IL18RAP | c.1671C>A p.Y557* | Nonsense Mutation (SNP) | VAF 79/290 reads (27%) | catalogued as COSV99962104; called by muse, mutect2, varscan2
- INPPL1 | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV99996318; called by muse, mutect2, varscan2
- INPPL1 | c.3701A>G p.E1234G | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99996320; called by muse, mutect2, varscan2
- IPCEF1 | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV99499872; called by muse, mutect2, varscan2
- IRX1 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57359716, COSV57362394; called by muse, mutect2, varscan2
- KDM6A | c.3147A>C p.E1049D | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV100938286; called by muse, mutect2
- KIAA0319 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV100985627, COSV65497903, COSV65498364; called by muse, mutect2, varscan2
- KLK14 | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.268); catalogued as COSV99335913; called by muse, mutect2
- LAMA2 | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV70349724, COSV99081519; called by muse, mutect2, varscan2
- LAMA2 | c.7889G>A p.R2630Q | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774656522, COSV70346451; called by muse, mutect2
- LARP7 | c.597A>G p.I199M | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs767609358, COSV100135207; called by muse, mutect2
- LARS1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.28); catalogued as COSV99198643; called by muse, mutect2
- LCAT | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99863104; called by muse, mutect2, varscan2
- LGI3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV60443201; called by muse, mutect2, varscan2
- LGI3 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV100103111; called by muse, mutect2, varscan2
- LRP1B | c.7925G>T p.G2642V | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV67220588; called by muse, mutect2, varscan2
- LRRC36 | c.1031A>G p.H344R | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99338807; called by muse, mutect2, varscan2
- LRRC40 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.173); catalogued as COSV100918796; called by muse, mutect2
- LRRK2 | c.1889T>A p.I630N | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100110468, COSV54141988; called by muse, mutect2, varscan2
- LRRTM1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV99702669; called by muse, mutect2
- MAGEA6 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100262851, COSV100262855; called by muse, mutect2, varscan2
- MARCHF4 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99814522; called by muse, mutect2, varscan2
- MCF2 | c.1613T>A p.L538Q | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58491683; called by muse, mutect2
- MEGF6 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99620577; called by muse, mutect2, varscan2
- MEP1A | c.1753G>T p.D585Y | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100042817; called by muse, mutect2, varscan2
- MMUT | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM060377, COSV99222382; called by muse, mutect2, varscan2
- MTR | c.3236A>T p.Y1079F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.074); catalogued as COSV100855410; called by muse, varscan2
- MYH13 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.99); PolyPhen benign (0.014); catalogued as COSV99353571, COSV99354319; called by muse, mutect2, varscan2
- MYH7 | c.5283+2T>A p.X1761_splice | Splice Site (SNP) | VAF 8/143 reads (6%) | catalogued as COSV100806220; called by muse, mutect2
- MYH8 | c.2006A>G p.H669R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV101238461; called by muse, mutect2, varscan2
- NDUFAF2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.657); catalogued as rs1378667377, COSV99681451; called by muse, mutect2, varscan2
- NEB | c.9769G>A p.D3257N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99420011; called by muse, mutect2
- NLGN4X | c.2036T>A p.I679N | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1181041551, COSV99322250; called by muse, mutect2, varscan2
- NLRP14 | c.765G>C p.L255F | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100205100; called by muse, mutect2, varscan2
- NUP210 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV54406217, COSV99596374; called by muse, mutect2, varscan2
- OLFML2A | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053739; called by muse, mutect2, varscan2
- OLFML2A | c.354+1G>T p.X118_splice | Splice Site (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100053742; called by muse, mutect2, varscan2
- OR51Q1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100332966; called by muse, mutect2
- OR6B3 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1038038787, COSV100097353; called by muse, mutect2, varscan2
- OR6F1 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57469923; called by muse, mutect2, varscan2
- OR8B4 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.33); catalogued as COSV100635829; called by muse, mutect2, varscan2
- OSBPL6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.98); catalogued as COSV99507680; called by muse, mutect2
- PADI2 | c.1441A>T p.I481F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV100970978; called by muse, mutect2, varscan2
- PADI4 | c.1557G>C p.K519N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.253); catalogued as COSV100966849; called by muse, mutect2
- PAK5 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100781398; called by muse, mutect2
- PALB2 | c.3440G>T p.C1147F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55171947; called by muse, mutect2, varscan2
- PER2 | c.3052G>C p.V1018L | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99612107; called by muse, mutect2, varscan2
- PEX5L | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs369361167, COSV55843464, COSV55844274; called by muse, mutect2, varscan2
- PFKFB2 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | PolyPhen probably damaging (1); catalogued as COSV100892003; called by muse, mutect2, varscan2
- PKHD1 | c.9401A>G p.K3134R | Missense Mutation (SNP) | VAF 92/355 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV100583431; called by muse, mutect2, varscan2
- PKHD1 | c.782T>C p.I261T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs398124493, COSV100583434; ClinVar: uncertain significance; called by muse, mutect2
- PLSCR1 | c.630G>T p.W210C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100678406; called by muse, mutect2, varscan2
- PLXNB3 | c.1895+1G>A p.X632_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as rs782150358, COSV62804124; called by muse, mutect2
- POLR1B | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99637878; called by muse, mutect2, varscan2
- POLR2I | c.132C>G p.Y44* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99387525; called by muse, mutect2, varscan2
- PRG2 | c.366+1G>T p.X122_splice | Splice Site (SNP) | VAF 15/107 reads (14%) | catalogued as rs755411858; called by muse, mutect2
- PRSS16 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100041781; called by muse, mutect2, varscan2
- PTPRZ1 | c.1344C>A p.D448E | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.339); catalogued as COSV101100238; called by muse, mutect2, varscan2
- RBMXL2 | c.706G>T p.G236* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100182294, COSV60978360; called by muse, mutect2
- RNF181 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV100110547, COSV57817626; called by muse, varscan2
- RNF214 | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 23/157 reads (15%) | catalogued as COSV100309406; called by muse, mutect2, varscan2
- ROBO4 | c.2260C>A p.L754I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV100127646, COSV60624020; called by muse, mutect2
- RPS6KA3 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV101084443; called by muse, mutect2, varscan2
- RUNX1T1 | c.179C>T p.P60L (on ENST00000265814 / NM_001198628.1; = p.P33L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); catalogued as COSV56152620, COSV56158222, COSV99752651; called by muse, mutect2, varscan2
- RYR2 | c.9959T>G p.L3320W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100770984; called by muse, mutect2, varscan2
- SCYL2 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100675216; called by muse, mutect2, varscan2
- SEPTIN11 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99346445; called by muse, mutect2
- SERTAD2 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV100512210; called by muse, mutect2, varscan2
- SFRP1 | c.637A>T p.I213L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV99617466; called by muse, mutect2, varscan2
- SH3BP4 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as COSV100749206; called by muse, mutect2, varscan2
- SLC25A40 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 102/627 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.192); catalogued as COSV100353711; called by muse, mutect2, varscan2
- SLC5A8 | c.1573A>G p.S525G | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.931); catalogued as COSV101610564; called by muse, mutect2, varscan2
- SLC7A14 | c.1747A>T p.I583F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV99200547; called by muse, mutect2, varscan2
- SLIT3 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60634554; called by muse, mutect2, varscan2
- SMARCA4 | c.3529G>T p.D1177Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60789707; called by muse, mutect2, varscan2
- SMPD3 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545747; called by muse, mutect2, varscan2
- SMYD4 | c.1442T>C p.L481S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100563077; called by muse, mutect2, varscan2
- SNX20 | c.834C>G p.Y278* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100319154, COSV100319227; called by muse, mutect2, varscan2
- SPAG17 | c.6293T>A p.V2098E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100309417; called by muse, mutect2, varscan2
- SPTA1 | c.4802A>G p.K1601R | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1326399541, COSV100935112; called by muse, mutect2, varscan2
- ST6GAL2 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 44/205 reads (21%) | PolyPhen benign (0.058); catalogued as COSV100868022; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | PolyPhen probably damaging (0.999); catalogued as rs116716486, COSV100083780; called by muse, mutect2, varscan2
- STBD1 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99421561; called by muse, varscan2
- STPG2 | c.1107T>G p.H369Q | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV99759773; called by muse, mutect2, varscan2
- TAS2R31 | c.629A>T p.Q210L | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101114993; called by muse, mutect2
- TBC1D21 | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100311379; called by muse, mutect2, varscan2
- TENM4 | c.6134A>G p.N2045S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs571774239, COSV99575575; called by muse, mutect2, varscan2
- TIAM2 | c.4695G>C p.E1565D (on ENST00000529824; = p.E1536D on NM_012454.3) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99265607; called by muse, mutect2, varscan2
- TMEM117 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV99861693, COSV99862871; called by muse, mutect2, varscan2
- TMEM225 | c.13T>A p.S5T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.942); catalogued as COSV100902823; called by muse, mutect2, varscan2
- TMEM255B | c.971A>G p.Y324C | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748536037, COSV64713200; called by muse, mutect2, varscan2
- TMEM259 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.072); catalogued as COSV99312624; called by muse, mutect2, varscan2
- TMEM63C | c.1412T>A p.V471D | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100029489; called by muse, mutect2, varscan2
- TRPM6 | c.2170T>G p.C724G | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100666506; called by muse, mutect2
- TTBK1 | c.1382G>T p.R461M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99444825; called by muse, mutect2, varscan2
- TTN | c.37282C>T p.R12428* (on ENST00000591111; = p.R5004* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/206 reads (9%) | catalogued as COSV59907035, COSV60415895; called by muse, mutect2
- TTN | c.33581C>A p.P11194H (on ENST00000591111; = p.P10267H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | PolyPhen possibly damaging (0.799); catalogued as COSV60362146; called by muse, mutect2
- TTN | c.19557G>T p.Q6519H (on ENST00000591111; = p.Q5592H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/158 reads (9%) | PolyPhen possibly damaging (0.563); catalogued as COSV100617482, COSV100617582; called by muse, mutect2
- TTN | c.6602C>G p.P2201R (on ENST00000591111; = p.P2155R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/127 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV100617483, COSV60245151; called by muse, mutect2, varscan2
- TUBD1 | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV100360137; called by muse, mutect2, varscan2
- UBE2M | c.34A>G p.K12E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs371025308; called by muse, mutect2, varscan2
- ULK3 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs775473939, COSV99173967; called by muse, mutect2, varscan2
- UROC1 | c.1781G>A p.G594D | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99331625; called by muse, mutect2, varscan2
- UTS2B | c.334+1G>C p.X112_splice | Splice Site (SNP) | VAF 52/260 reads (20%) | catalogued as COSV100484245; called by muse, mutect2, varscan2
- VPS37A | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV100246626; called by muse, mutect2, varscan2
- WRN | c.1496G>T p.R499I | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53296800; called by muse, varscan2
- WSCD2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV54580843; called by muse, mutect2, varscan2
- XRN1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99378201; called by muse, mutect2, varscan2
- XRN2 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101018408, COSV65868226; called by muse, mutect2
- ZBTB4 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV60981429; called by muse, mutect2, varscan2
- ZEB2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100356252; called by muse, mutect2, varscan2
- ZFAND4 | c.959A>G p.D320G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100762997; called by muse, mutect2
- ZFAND4 | c.329-1G>T p.X110_splice | Splice Site (SNP) | VAF 29/107 reads (27%) | catalogued as rs867358284, COSV100084428; called by muse, mutect2, varscan2
- ZFP82 | c.139T>A p.C47S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101089128; called by muse, mutect2, varscan2
- ZNF142 | c.5134G>T p.E1712* (on ENST00000411696 / NM_001379660.1; = p.E1512* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV101346909; called by muse, mutect2, varscan2
- ZNF445 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101253799; called by muse, mutect2, varscan2
- ZNF692 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100133861; called by muse, mutect2, varscan2
- ZNF704 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 161/469 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); catalogued as COSV100589543, COSV59926877; called by muse, mutect2, varscan2
- ZNHIT2 | c.961C>T p.R321W | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99659362; called by muse, mutect2, varscan2
- AEBP1 | c.1234del p.A412Hfs*33 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CXCR1 | c.139del p.A47Pfs*2 | Frame Shift Del (DEL) | VAF 24/246 reads (10%) | called by mutect2, pindel, varscan2
- FOXP1 | c.952_960del p.E318_F320del | In Frame Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel, varscan2
- LCN2 | c.328_340del p.G110Wfs*10 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- OR2T10 | c.742del p.V248Sfs*25 | Frame Shift Del (DEL) | VAF 9/70 reads (13%) | called by mutect2, pindel, varscan2
- TRGV5 | c.218C>G p.S73* | Nonsense Mutation (SNP) | VAF 27/154 reads (18%) | called by muse, mutect2, varscan2
- A2M | c.1335T>C p.H445= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100588745; called by muse, mutect2, varscan2
- ADGRV1 | c.7308G>C p.L2436= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV101316100; called by muse, mutect2, varscan2
- AGAP2 | c.2541G>T p.S847= (on ENST00000547588 / NM_001122772.2; = p.S511= on NM_014770.4) | Silent (SNP) | VAF 27/210 reads (13%) | catalogued as COSV99223466; called by muse, mutect2, varscan2
- AHNAK2 | c.13275T>A p.S4425= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as COSV100317846; called by muse, mutect2, varscan2
- AMIGO3 | c.549C>T p.T183= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs747864514, COSV100246636; called by muse, mutect2, varscan2
- ANK2 | c.2748G>T p.L916= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100002120; called by muse, mutect2, varscan2
- ARMC12 | c.534A>T p.P178= (on ENST00000373866 / NM_001286574.2; = p.P205= on NM_145028.5) | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV99849483; called by muse, mutect2, varscan2
- AZGP1 | c.90G>T p.L30= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as COSV52798623, COSV99447993; called by muse, mutect2, varscan2
- CACNA1B | c.3867C>T p.Y1289= | Silent (SNP) | VAF 68/242 reads (28%) | catalogued as COSV99498000; called by muse, mutect2, varscan2
- CCDC60 | c.387A>G p.T129= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100555266; called by muse, mutect2, varscan2
- CCT8L2 | c.1143C>T p.T381= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100742827, COSV63463197; called by muse, mutect2
- CDH18 | c.2091C>T p.L697= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV99935714; called by muse, mutect2
- CNOT1 | c.486C>T p.D162= | Silent (SNP) | VAF 63/441 reads (14%) | catalogued as rs1048515497, COSV100409475; called by muse, mutect2, varscan2
- COLEC12 | c.1443G>C p.A481= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV101232093; called by muse, mutect2, varscan2
- CSMD3 | c.10665C>T p.R3555= (on ENST00000297405 / NM_001363185.1; = p.R3386= on NM_052900.3) | Silent (SNP) | VAF 102/332 reads (31%) | catalogued as COSV99836912; called by muse, mutect2, varscan2
- DMD | c.4680A>C p.T1560= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100820234; called by muse, mutect2
- DOCK1 | c.450A>T p.T150= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99730370; called by muse, mutect2, varscan2
- FAM47C | c.120C>T p.F40= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100792686; called by muse, varscan2
- FCRLA | c.387A>G p.P129= (on ENST00000367959; = p.P106= on NM_032738.4) | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV99376211; called by muse, mutect2
- FRMPD2 | c.2076G>A p.Q692= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs1241931827, COSV59719239; called by muse, mutect2, varscan2
- GATA2 | c.300G>T p.G100= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1475853382, COSV100351368; called by muse, mutect2
- GOT1L1 | c.156G>T p.V52= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100294556; called by muse, mutect2, varscan2
- HENMT1 | c.195A>G p.L65= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs754595447, COSV100898667; called by muse, mutect2, varscan2
- HIVEP1 | c.5238G>A p.R1746= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV101045211; called by muse, mutect2, varscan2
- HS3ST4 | c.1164C>T p.F388= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs528453170, COSV58823523; called by muse, mutect2
- INSC | c.726G>C p.L242= | Silent (SNP) | VAF 52/228 reads (23%) | catalogued as COSV101089267, COSV101089785; called by muse, mutect2, varscan2
- IPO8 | c.3009G>A p.T1003= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs534882683, COSV99805443; called by muse, mutect2, varscan2
- KARS1 | c.783G>A p.L261= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs1038012468, COSV100094174; called by muse, mutect2, varscan2
- LRRC7 | c.1128C>A p.P376= (on ENST00000651989 / NM_001370785.2; = p.P343= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1260777634, COSV50596970; called by muse, mutect2, varscan2
- LRRTM1 | c.1284G>T p.V428= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV99702666; called by muse, mutect2, varscan2
- MAGEA6 | c.618G>T p.L206= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV100262854; called by muse, mutect2, varscan2
- MCF2 | c.1612C>T p.L538= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as COSV100644838, COSV58483393; called by muse, mutect2
- MCM2 | c.2469A>T p.S823= | Silent (SNP) | VAF 63/298 reads (21%) | catalogued as COSV99413211; called by muse, mutect2, varscan2
- MUC7 | c.696A>G p.P232= | Silent (SNP) | VAF 24/336 reads (7%) | catalogued as COSV100512327; called by muse, mutect2
- NLRP13 | c.1587G>A p.G529= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- OBSCN | c.10686C>T p.N3562= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as COSV99479974; called by muse, mutect2, varscan2
- OR2M5 | c.246C>A p.A82= | Silent (SNP) | VAF 45/479 reads (9%) | catalogued as COSV63547349; called by muse, mutect2
- OR2M7 | c.66C>A p.P22= | Silent (SNP) | VAF 60/356 reads (17%) | catalogued as COSV100522582; called by muse, mutect2, varscan2
- OR5B21 | c.111G>A p.L37= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV100835156; called by muse, mutect2, varscan2
- OR6F1 | c.444C>G p.S148= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as rs776848829, COSV100128858, COSV100129238; called by muse, mutect2, varscan2
- OR6T1 | c.21T>A p.T7= | Silent (SNP) | VAF 43/168 reads (26%) | catalogued as COSV100190013; called by muse, mutect2, varscan2
- PGM2 | c.1725A>C p.P575= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV101126598; called by muse, mutect2, varscan2
- PKLR | c.960G>A p.V320= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs1161341734, COSV100712920; called by muse, mutect2, varscan2
- PTPRM | c.1353A>G p.P451= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs762804618, COSV100157900; called by muse, mutect2, varscan2
- SLC12A3 | c.2715T>C p.A905= (on ENST00000563236 / NM_001126108.2; = p.A914= on NM_000339.3) | Silent (SNP) | VAF 30/213 reads (14%) | catalogued as COSV99344259, COSV99344328; called by muse, mutect2, varscan2
- SLC22A16 | c.96C>A p.I32= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV100397518; called by muse, mutect2, varscan2
- SLC4A1 | c.2730T>A p.P910= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99293394; called by mutect2, varscan2
- SLC9A4 | c.21G>A p.V7= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV54828987; called by muse, mutect2, varscan2
- SSH1 | c.2529C>T p.S843= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1477654653, COSV100425617; called by muse, mutect2, varscan2
- STXBP5L | c.1275G>A p.L425= | Silent (SNP) | VAF 7/121 reads (6%) | catalogued as COSV99874690; called by muse, mutect2
- SYNE1 | c.20565G>A p.L6855= (on ENST00000367255 / NM_182961.4; = p.L6784= on NM_033071.3) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV54969845; called by muse, mutect2
- TBCEL | c.495A>C p.T165= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV99412223; called by muse, mutect2, varscan2
- TENM4 | c.3219T>G p.S1073= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as COSV99575579; called by muse, mutect2
- TFEC | c.804T>C p.S268= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as COSV99624606; called by muse, mutect2, varscan2
- THAP4 | c.1680G>A p.T560= | Silent (SNP) | VAF 34/274 reads (12%) | catalogued as rs146802008; called by muse, mutect2, varscan2
- TRIM54 | c.789G>T p.L263= (on ENST00000380075 / NM_187841.3; = p.L305= on NM_032546.4) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs759272449, COSV99274402; called by muse, mutect2, varscan2
- TSC2 | c.4716G>A p.T1572= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs369346726, COSV99238313; ClinVar: benign; called by muse, mutect2, varscan2
- UBASH3A | c.1662G>A p.P554= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs779550815, COSV52316652; called by mutect2, varscan2
- VWF | c.2097G>T p.G699= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV99779341; called by muse, mutect2, varscan2
- WDR59 | c.234G>A p.A78= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs142883546; called by muse, mutect2, varscan2
- COLEC11 | c.203-11456G>A | Intron (SNP) | VAF 21/256 reads (8%) | catalogued as COSV52591434, COSV99363348; called by muse, mutect2
- EGFR | c.1881-825A>G | Intron (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99292034; called by muse, mutect2
- RBM44 | c.-98-2164T>G | Intron (SNP) | VAF 39/166 reads (23%) | catalogued as COSV100389927; called by muse, mutect2, varscan2
- XIST | n.8443G>T | RNA (SNP) | VAF 76/146 reads (52%) | called by muse, mutect2, varscan2
